TCGA case TCGA-OR-A5JZ — Adrenocortical Carcinoma (TCGA-ACC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Adrenal gland; Tissue source site: University of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/94cdac79-2b4e-483a-8f17-3e0c9be589d0

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Alive.

Diagnoses (3)
1. Adrenal cortical carcinoma (the primary disease): ICD-O-3 morphology code: 8370/3; ICD-10 code: C74.0; Tissue or organ of origin: Cortex of adrenal gland; Site of resection or biopsy: Adrenal gland, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 60.8 years (22,218 days); Year of diagnosis: 2011; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 822 days (2.3 years); Ensat clinical m: M0; Ensat pathologic n: N0; Ensat pathologic stage: Stage II; Ensat pathologic t: T2; Weiss assessment findings: Invasion of Tumor Capsule / Necrosis.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 16 days; Days to treatment end: 85 days; Treatment dose: 55 Gy; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Mitotane; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease; Therapeutic levels achieved: No; Therapeutic target level: >14 mg/L.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
2. Metastasis of diagnosis 1 (Adrenal cortical carcinoma), site: Tail of pancreas. Age at diagnosis: 61.5 years (22,465 days); Days to diagnosis: 247 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Adrenal cortical carcinoma), site: Liver. Age at diagnosis: 61.5 years (22,465 days); Days to diagnosis: 247 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (6 entries)
- Day 211 (within 3 months of surgery): Disease response: Tumor Free.
- Day 247 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Tail of pancreas; Days to progression: 247 days; Evidence of progression type: Convincing Image Source.
- Day 247 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 247 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 822 days (2.3 years); Disease response: With Tumor.
- Day 822 (within 3 months of surgery): Disease response: Tumor Free.
- Imaging type: CT Scan; Imaging findings: Normal; Timepoint: Preoperative.

Molecular and laboratory tests
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-OR-A5JZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 130 mg.
  Slide TCGA-OR-A5JZ-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 4; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-OR-A5JZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-OR-A5JZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Pharmaceutical treatment mitotane indicator: Yes; Pharmaceutical treatment mitotane theraputic levels: No; Clinical status within 3 mths surgery: No imaging evidence of disease.
- Primary pathology: Submitted tumor site: Adrenal; Histologic diagnosis: Adrenocortical carcinoma- Usual Type; Ct scan preop results: Yes; Lymph nodes examined: No; Mitoses per 50 hpf: 5.
- Primary pathology, Weiss assessment report, Weiss assessment categories: Mitotic rate: Mitotic Rate > 5/50 HPF Absent; Necrosis: Necrosis Present; Weiss venous invasion: Venous Invasion Absent; Invasion of tumor capsule: Invasion of Tumor Capsule Present.
- Primary pathology, Germline genotype testing report: Molecular studies others performed: Yes.
- Follow-up form: Lost to follow-up: No; Pharmaceutical treatment mitotane theraputic levels: No; Clinical status within 3 mths surgery: No imaging evidence of disease; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 822 days; disease-specific survival: no event (censored), 822 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 247 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-OR-A5JZ-01A-11D-A29H-01): tumor purity 0.95, ploidy 1.21, whole-genome doublings 0.
